CCDI case PBBWZD — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Connective, subcutaneous and other soft tissues.
https://portal.gdc.cancer.gov/cases/c0e3713b-4d18-4fdc-a440-a574bdfbd125

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8900/3; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of upper limb and shoulder; Age at diagnosis: 1.7 years (639 days).

Biospecimens (3 samples)
- Sample 0DJPCK: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DJPCR: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DJPD6: Tissue type: Tumor; Specimen type: Solid Tissue.
